Somatic mutation profile of tumor specimen 0DFJMX from CCDI case PBBSGI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.2 years (2,271 days).
Specimen 0DFJMX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a1052d-4604-478a-8be8-4d6201fd179e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJJ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c335d0c-4574-4712-ad56-16aebbcffdf2

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 3, Silent 3, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 184/338 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FCAR | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 85/360 reads (24%) | catalogued as rs766003893, COSV62028348, COSV62029418; called by muse, mutect2, varscan2
- TP53 | c.457_460dup p.G154Afs*28 | Frame Shift Ins (INS) | VAF 132/376 reads (35%) | catalogued as COSV53792382; called by mutect2, varscan2
- ZSWIM4 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 153/587 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1183415050; called by muse, mutect2, varscan2
- ACTN4 | c.2597A>T p.E866V | Missense Mutation (SNP) | VAF 40/601 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CLIC6 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 118/187 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FAM166A | c.539G>T p.R180M | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PAPLN | c.2035G>A p.A679T (on ENST00000554301; = p.A652T on NM_173462.4) | Missense Mutation (SNP) | VAF 134/211 reads (64%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SHROOM4 | c.4182C>G p.N1394K | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- SLC47A1 | c.1651C>A p.L551M | Missense Mutation (SNP) | VAF 101/474 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- TP53 | c.373dup p.T125Nfs*24 | Frame Shift Ins (INS) | VAF 106/281 reads (38%) | called by mutect2, pindel, varscan2
- CA11 | c.805C>T p.L269= | Silent (SNP) | VAF 196/460 reads (43%) | called by muse, mutect2, varscan2
- DHX15 | c.66C>T p.T22= | Silent (SNP) | VAF 62/192 reads (32%) | catalogued as rs756811130; called by muse, mutect2, varscan2
- STPG3 | c.777C>T p.F259= | Silent (SNP) | VAF 96/391 reads (25%) | called by muse, mutect2, varscan2
- CNTLN | c.449+23648dup | Intron (INS) | VAF 11/56 reads (20%) | catalogued as rs761617351; called by mutect2, pindel, varscan2
- MICALL2 | c.144-73G>T | Intron (SNP) | VAF 80/186 reads (43%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2593C>T | Intron (SNP) | VAF 115/804 reads (14%) | catalogued as rs777893854, COSV52752484; called by muse, mutect2, varscan2
